Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3N3, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3N3-01A (Primary Tumor).

History Case Pathology Report

Department of Pathology,

Tel:

DOB:

Sex: F

Physician:

Received:

Pathologist:

Accession:

Case type: Surgical History

**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to section "SPECIMEN" may have been added. ****

DIAGNOSIS

(A) RULE OUT RIGHT INFERIOR PARATHYROID:
Parathyroid gland.

(B) TOTAL THYROIDECTOMY:

PAPILLARY CARCINOMA OF THYROID IN LEFT LOBE WITH EXTRA-GLANDULAR
EXTENSION. MARGINS OF EXCISION FREE. (TUMOR MEASURING 1.5 CM).
One parathyroid gland, no tumor.
Follicular adenoma right lobe of thyroid.
Nodular goiter.
Chronic inflammation.
Benign lymphoid follicles in thyroid.

ICD-0-3
carcinoma, papillary, thyroid 8260/3
Site = thyroid, NOS C73.9 lw
1/7/12

Entire report and diagnosis completed by:
Report released by:

GROSS DESCRIPTION

(A) RULE OUT RIGHT INFERIOR PARATHYROID - Tan tissue fragment (0.6 x 0.2 x 0.2 cm). A, submitted in toto for frozen section.

*FS/DX: PARATHYROID GLAND.

(B) TOTAL THYROIDECTOMY - A total thyroidectomy with overall measurements of 6.0 x 4.5 x 2.0 cm. The left lobe is smaller than the right lobe and appears to be homogeneous, small, white-tan and firm nodule abutting the deep margin grossly measuring 1.5 cm is noted located in the anterior aspect of the thyroid lobe. The right lobe is multinodular and several small oncocyctic to colloid nodules are identified ranging from 0.5 to 1.5 cm in diameter. Representative sections are submitted under B2-B6; left lobe and tumor in B7-B17; right lobe with multiple nodules.

*FS/DX: PAPILLARY CARCINOMA.

SNOMED CODES

M-80503 T-B6000

Source: NCI Genomic Data Commons file ad19e786-839c-410a-9f8c-3164cd02558e (TCGA-EL-A3N3.83780FF8-5F40-4635-B8C1-903B6718B6DC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).